CPTAC case C3N-03003 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c7f5c470-0c40-4780-bd1e-7d9d1141d4dd

Demographics
Sex at birth: male; Race: white; Year of birth: 1977; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Frontal lobe; Age at diagnosis: 40.1 years (14,654 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 737 days (2.0 years); Progression or recurrence: yes; Days to recurrence: 633 days (1.7 years); Days to last follow up: 737 days (2.0 years).
   Pathology details: Greatest tumor dimension: 4 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 396 days (1.1 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 737 days (2.0 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 633 days (1.7 years); Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 737 days (2.0 years); Disease response: With Tumor; Karnofsky performance status: 100; ECOG performance status: 0.

Other clinical attributes
- Weight: 95 kg; Height: 180 cm; BMI: 29.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03003-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 571 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03003-21: Section location: Frontal Lobe; Percent tumor nuclei: 90; Percent necrosis: 2.
- Sample C3N-03003-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -10 days; Method of sample procurement: Blood Draw.
